National Lung Screening Trial (NLST) participant 112013 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 69 years; Gender: female; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 15): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 70 mA, 43 effective mAs, display field of view 31 cm, reconstruction filter GE, other.
- T1 (day 379): Positive, no significant change: stable abnormalities potentially related to lung cancer, unchanged since the prior screening exam. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 70 mA, 37 effective mAs, display field of view 31 cm, reconstruction filter GE Standard / GE Bone.
- T2 (day 708): Negative screen, minor abnormalities not suspicious for lung cancer. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 70 mA, 37 effective mAs, display field of view 30 cm, reconstruction filter GE Standard / GE Bone.

Abnormalities recorded by the reading radiologist on the CT screens (13 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 6 mm, longest perpendicular diameter 4 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 21.
- T0 abnormality 2: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T0 abnormality 3: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T0 abnormality 4: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 5 mm, longest perpendicular diameter 5 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 19; pre-existing on earlier images (earliest visible day 15); no interval growth; no suspicious change in attenuation.
- T1 abnormality 2: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 3: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 4: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 22; pre-existing on earlier images (earliest visible day 15); no interval growth; no suspicious change in attenuation.
- T2 abnormality 2: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 3: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 4: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 5: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,232.
